Surgical pathology report (de-identified scan), TCGA case TCGA-51-4081, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-51-4081-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

A: Lymph node, Level 7, removal

- No tumor seen in multiple lymph node fragments (see comment).

B: Lymph node, Low 4R, removal

- No tumor seen in multiple lymph node fragments (see comment).

C: Lymph node, High 4R, removal

- No tumor seen in multiple lymph node fragments (see comment).

D: Lung, right upper lobe, lobectomy

Tumor histologic type (WHO classification): invasive
moderately
differentiated keratinizing squamous cell carcinoma

Tumor histologic grade (WHO classification): moderately
differentiated

Tumor size (greatest dimension): 3.5 cm

Other structures involved: none

Pleural involvement: not identified

In situ carcinoma: present

[page 2 of 5]
Invasion:

venous - not identified
arterial - not identified
lymphatic - lymphovascular space invasion identified
perineural - not identified

Histologic assessment of surgical margins: negative

Lymph nodes: One peribronchial lymph node of 11 lymph nodes involved by metastatic carcinoma, in this specimen.

Extracapsular extension of tumor in lymph nodes: not identified

AJCC Staging:

pT2a
pN1
pMx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

E: Lymph nodes, Level 7, removal
- No tumor seen in four lymph nodes (0/4).

F: Lymph node, Level 11, right, removal
- No tumor seen in one lymph node (0/1).

Comment:

The frozen section diagnoses are confirmed.

Intraoperative Consult Diagnosis:

Frozen section was requested by [REDACTED]

FSA1: "Level 7", excision
- Negative for carcinoma

FSB1: "Low 4R", excision
- Negative for carcinoma

FSC1: "Level High 4R", excision
- Negative for carcinoma

[page 3 of 5]
FSD1/FSD2: "Proximal margin", right upper lobe, excision
- Negative for carcinoma

FSD3: "Distal margin", right upper lobe, excision
- Negative for carcinoma

Frozen Section Pathologist:

Clinical History:

a three week history of fatigue and productive cough. CT scan demonstrated a right upper lobe lung mass consistent with carcinoma (bronchogenic). Mediastinal adenopathy was present. The patient also has bilateral adrenal masses and a [REDACTED]

Gross Description:

Received are six appropriately labeled containers.

Container A is additionally labeled "Level 7." At the time of frozen section, the specimen was noted to measure 1.6 x 1.2 x 0.3 cm. The tissue fragments were submitted in block FSA1, NTR.

Container B is additionally labeled "Low 4R." At the time of frozen section, the specimen was noted to measure 1.6 x 0.8 x 0.2 cm. It was three red/tan soft tissue fragments submitted entirely in block FSB1, NTR.

Container C is additionally labeled "High 4R." At the time of frozen section, the specimen was noted to measure 3 x 2 x 0.5 cm. It was multiple red/tan soft tissue fragments submitted entirely in block FSC1 and FSC2, NTR.

Container D is additionally labeled "right upper lobe." At the time of frozen section, the specimen was noted to measure 17 x 8 x 5 cm. The proximal margin was inked blue, and submitted as FSD1-FSD2. The distal margin was inked black and submitted as FSD3.

Specimen fixation: formalin

Type of specimen/parts of lung received: right upper lobe

[page 4 of 5]
Size of specimen: see above

Weight of specimen: 197 grams (after formalin fixation)

Other attached structures: none

Orientation: A small amount of yellow ink is present on one of the pleural surfaces where an incision was made during Tissue Procurement. An exposed bronchial margin is present with surrounding blue and black ink. Of note, the remainder of the external surface is inked black. The surgical staple line is removed and the undersurface is inked blue. The surgical staple line measures 6 cm in length.

Tumor location: The tumor is located in the central part of the specimen, and is close to both the main bronchus and pleural surface. The tumor is also close to the blue inked surgical staple lines of resection.

Tumor size: 3.5 x 3.0 x 3.0 cm

Relationship of tumor to bronchus: The tumor does appear to come very close to the bronchus, and may in fact invade it. There is mucus in the bronchial lumen approximately 1 cm from the bronchial margin.

Distance of tumor to bronchial margin: Somewhat difficult to grossly identify since the specimen has already been sampled during the frozen section. It can be estimated that the tumor is 1 cm from the bronchial margin.

Relationship/distance of tumor to pleura: The tumor does appear to directly abut the pleural surface (within 0.1 cm).

Distance of tumor to other surgical margins: tumor approaches close to the blue inked staple line

Presence/absence of satellite tumor nodules: The main mass appears to be solitary. The remainder of the lung tissue does have some consolidation and mucus plugging, but no definitive carcinoma is identified elsewhere.

Involvement of attached structures by tumor: n/a

Description of nontumorous lung: The non-tumorous lung is spongy, brown, with areas of viscous mucus.

[page 5 of 5]
Tissue submitted for special investigation: Tumor and normal tissue are submitted to Tissue Procurement for special study.

Block Summary:

- D1 - representative section near bronchial margin (superseded by frozen section) and representative hilar lymph node
- D2 - representative section of tumor and relation to large bronchus
- D3 - relationship of tumor to surgical staple line of resection
- D4 - representative section of adjacent lung parenchyma with obstructive changes
- D5 - relationship of tumor to pleural surface
- D6 - relationship to tumor to adjacent uninvolved lung
- D7 - relationship of tumor to large vessel
- D8 - representative lymph node close to tumor
- D9, D10 - additional representative sections of lung

Container E is additionally labeled "lymph node." The container holds multiple unoriented candidate lymph nodes, one of which measures 2.0 x 1.0 x 1.0 cm, the other which measures 2.0 x 1.0 x 0.5 cm. The tissue is tan/brown and unremarkable.

Block summary:

- E1 - one candidate lymph node
- E2 - one large candidate lymph node
- E3 - two candidate lymph nodes, NTR

Container F is additionally labeled "11 right." It holds an unoriented soft tissue fragment consistent with a lymph node candidate. There is one staple present in the specimen that is removed. The specimen measures 1.0 x 1.0 x 0.5 cm. The lymph node is tan and unremarkable. The lymph node candidate is submitted in block F1, NTR.

Light Microscopy:

Light microscopic examination is performed by ■.

Source: NCI Genomic Data Commons file bff4a0ac-b323-4655-b10a-d6a77ec4487f (TCGA-51-4081.0BF5AACF-58AB-45DD-B257-2D56045B9877.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).